Somatic mutation profile of tumor specimen MP2PRT-PANSJJ-TMP1-A (aliquot MP2PRT-PANSJJ-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANSJJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (1,000 days).
Specimen MP2PRT-PANSJJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf7e31da-8008-41a2-a975-474687c640fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANSJJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANSJJ-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a315e633-1c66-40ea-b522-5dcd3616fe9d

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, 3'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C11orf86 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 164/695 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs747999511, COSV58296827; called by muse, mutect2, varscan2
- CDH8 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 119/504 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as rs780237284, COSV100181522; called by muse, mutect2, varscan2
- CDHR5 | c.1742G>C p.G581A (on ENST00000358353 / NM_001171968.2; = p.G587A on NM_021924.5) | Missense Mutation (SNP) | VAF 108/1388 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100363888; called by muse, mutect2
- DOCK3 | c.3177G>T p.R1059S | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV56541610; called by muse, mutect2, varscan2
- FSHR | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 42/576 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99065633; called by muse, mutect2
- HOOK1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs367708992; called by muse, mutect2, varscan2
- PLEKHA7 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 83/864 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772989794, COSV63050832; called by muse, mutect2
- ROS1 | c.6265G>A p.V2089M | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs750308356, COSV63852512; called by muse, mutect2
- SLC25A52 | c.262C>T p.R88* (on ENST00000672005; = p.R78* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 67/515 reads (13%) | catalogued as COSV52502938; called by muse, mutect2, varscan2
- ATP9A | c.1124C>G p.S375C | Missense Mutation (SNP) | VAF 24/720 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- FOS | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 48/762 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- IGHV3-53 | c.347_348insCCCTCGAG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 15/90 reads (17%) | called by muse*, pindel, varscan2
- IGKV1D-8 | chr2:90221358 del CTGTCAACAGTATTATAGTTTCCCTCCCACAGTGTTACAC | Missense Mutation (DEL) | VAF 18/148 reads (12%) | called by mutect2, pindel
- PDE3A | c.2936A>C p.E979A | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SNRNP27 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 91/664 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- UBA2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- USP11 | c.488G>C p.W163S (on ENST00000218348; = p.W120S on NM_001371072.1) | Missense Mutation (SNP) | VAF 95/631 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZHX3 | c.2039C>G p.S680C | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ATM | c.99G>C p.L33= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- KIAA2012 | c.2394C>T p.N798= | Silent (SNP) | VAF 42/251 reads (17%) | catalogued as rs770781103; called by muse, mutect2, varscan2
- KRT79 | c.108G>A p.V36= | Silent (SNP) | VAF 137/669 reads (20%) | called by muse, mutect2, varscan2
- PRTG | c.3222G>A p.A1074= | Silent (SNP) | VAF 106/257 reads (41%) | catalogued as rs1287206397; called by muse, mutect2, varscan2
- SMCO2 | c.756G>C p.T252= | Silent (SNP) | VAF 88/472 reads (19%) | called by muse, mutect2, varscan2
- SOAT2 | c.540G>A p.A180= | Silent (SNP) | VAF 105/838 reads (13%) | catalogued as rs1476633603; called by muse, mutect2, varscan2
- ZSCAN5C | c.855C>T p.S285= | Silent (SNP) | VAF 63/486 reads (13%) | catalogued as rs538025264; called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005629 ins CGTC | 3'Flank (INS) | VAF 46/123 reads (37%) | called by mutect2, varscan2
